Somatic mutation profile of tumor specimen TCGA-VN-A88O-01A (aliquot TCGA-VN-A88O-01A-11D-A34U-08) from TCGA case TCGA-VN-A88O, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 49.1 years (17,945 days).
Specimen TCGA-VN-A88O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7be4d90e-e479-4af1-a38e-7bd7276f2b0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VN-A88O-10A (Blood Derived Normal), aliquot TCGA-VN-A88O-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e2d9c3b-ca0f-478a-9012-eeb9f5c2e1cb

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 19, Silent 10, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.373T>A p.F125I | Missense Mutation (SNP) | VAF 47/146 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100753178, COSV100753463, COSV61654162; called by muse, mutect2, varscan2
- ACSBG1 | c.2024G>T p.R675L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV51911549, COSV99357610; called by muse, mutect2, varscan2
- ACTL8 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1165059846, COSV100958717; called by muse, mutect2, varscan2
- CLK1 | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100362359; called by muse, mutect2
- DEPP1 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100024451, COSV100024508; called by muse, mutect2, varscan2
- FILIP1 | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99385366; called by muse, mutect2
- FNDC1 | c.2872G>A p.A958T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1417434518, COSV51947634; called by muse, mutect2
- HUWE1 | c.12365G>A p.R4122H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53336640; called by muse, mutect2, varscan2
- IKBIP | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.421); catalogued as COSV100689846; called by muse, mutect2, varscan2
- LY75 | c.4700-1G>T p.X1567_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99716679; called by muse, mutect2, varscan2
- MRPL13 | c.410T>G p.I137S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100085523; called by muse, mutect2
- NIPSNAP3B | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV101044491; called by muse, mutect2
- NRG3 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.901); catalogued as rs749884304, COSV64544784; called by muse, mutect2, varscan2
- OMA1 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.057); catalogued as COSV100678271; called by muse, mutect2
- PGLYRP2 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV99484161; called by muse, mutect2, varscan2
- PROKR1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748220604, COSV58136678; called by muse, mutect2, varscan2
- PROKR2 | c.570C>A p.Y190* | Nonsense Mutation (SNP) | VAF 6/140 reads (4%) | catalogued as COSV99450465; called by muse, mutect2
- PTPN4 | c.23C>G p.P8R | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.732); catalogued as COSV99750615; called by muse, mutect2, varscan2
- SPEG | c.3664T>C p.F1222L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.744); catalogued as COSV100405006; called by muse, mutect2
- TAF1D | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as rs761554639, COSV100126995; called by muse, mutect2, varscan2
- USP40 | c.1807G>A p.G603R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs376670354; called by muse, mutect2, varscan2
- ZMYND12 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780595276, COSV65341759; called by muse, mutect2, varscan2
- NXPH2 | c.260_262del p.I87del | In Frame Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- ZNF326 | c.735dup p.N246* | Frame Shift Ins (INS) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- ADCY4 | c.2346C>T p.P782= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV60253598; called by muse, mutect2, varscan2
- APOA4 | c.723G>A p.L241= | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as COSV100759336, COSV100759359; called by muse, mutect2, varscan2
- CUL5 | c.2016C>T p.F672= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs748500386, COSV101263717; called by muse, mutect2, varscan2
- FBXO42 | c.150G>T p.L50= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs751146684, COSV100981844; called by muse, mutect2, varscan2
- MUC3A | c.7032G>A p.S2344= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as rs745350496, COSV60215974; called by muse, mutect2, varscan2
- OR52E2 | c.42C>T p.F14= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV58612143; called by muse, mutect2
- SLC39A10 | c.495A>G p.K165= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV100660676; called by muse, mutect2, varscan2
- SNPH | c.252G>T p.V84= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV101118903; called by muse, mutect2
- TBC1D1 | c.2310A>G p.V770= | Silent (SNP) | VAF 7/140 reads (5%) | catalogued as COSV99791654; called by muse, mutect2
- ZNF830 | c.594G>T p.R198= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100030835; called by muse, mutect2
